Somatic mutation profile of tumor specimen HCM-BROD-0648-C71-86R (aliquot HCM-BROD-0648-C71-86R-01D-A937-36) from HCMI case HCM-BROD-0648-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,260 days).
Specimen HCM-BROD-0648-C71-86R: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4afb77bd-d142-4283-9ed6-b33d573d6ac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0648-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0648-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0d556fd-c436-475c-bc4e-48545b4d2eca

The open-access MAF lists 6,595 somatic variants for this specimen: 4,179 protein-altering or splice-affecting, 2,133 silent, 283 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,867, Silent 2,133, Intron 163, Nonsense Mutation 145, Splice Site 85, Splice Region 66, 3'UTR 35, 5'UTR 31, 5'Flank 23, 3'Flank 20, RNA 11, Frame Shift Del 8.

Variants (750 of 6,595; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.7793G>A p.G2598D | Missense Mutation (SNP) | VAF 176/382 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs527236064, CM121440; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYS | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 28/455 reads (6%) | catalogued as rs1388177618; ClinVar: pathogenic; called by muse, mutect2
- FBXW7 | c.584+1G>A p.X195_splice (on ENST00000281708 / NM_001349798.2; = p.X115_splice on NM_018315.5) | Splice Site (SNP) | VAF 17/200 reads (9%) | hotspot (GDC flag); catalogued as COSV55919936, COSV55962288; called by muse, mutect2
- KMT2D | c.15641G>A p.R5214H | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MSH6 | c.2910G>A p.W970* | Nonsense Mutation (SNP) | VAF 187/369 reads (51%) | catalogued as rs765411990, COSV52286399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSN | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 43/267 reads (16%) | catalogued as rs1057519075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEB | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 135/259 reads (52%) | catalogued as rs1553548666, CM1513203, COSV99428271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 67/148 reads (45%) | catalogued as rs746824139, CM992365, CX1512904, COSV62195847; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 261/358 reads (73%) | catalogued as rs786204884, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC26A4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 101/385 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1562822565, CM011489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 109/242 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1553857889, COSV53197508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735822; called by muse, mutect2, varscan2
- AAK1 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV68642789; called by muse, mutect2, varscan2
- AASS | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 191/657 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750821357; called by muse, varscan2
- ABCA12 | c.4551A>G p.I1517M (on ENST00000272895 / NM_173076.3; = p.I1199M on NM_015657.3) | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1353780476; called by muse, mutect2
- ABCA13 | c.1492-1G>A p.X498_splice | Splice Site (SNP) | VAF 23/137 reads (17%) | catalogued as rs1430955464; called by muse, mutect2, varscan2
- ABCA2 | c.6854G>A p.R2285Q (on ENST00000614293; = p.R2255Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1423548812; called by muse, mutect2, varscan2
- ABCA4 | c.6190G>A p.A2064T | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs61753040, CM032820, CM161749; called by muse, varscan2
- ABCB11 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1403850332, COSV55601803; called by muse, varscan2
- ABCB11 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424715238; called by muse, mutect2
- ABCC11 | c.2475G>A p.W825* | Nonsense Mutation (SNP) | VAF 116/269 reads (43%) | catalogued as rs750609137, COSV62322921; called by muse, mutect2, varscan2
- ABCC12 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV60916513; called by muse, mutect2, varscan2
- ABCE1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99668581; called by muse, mutect2, varscan2
- ABCG2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1160489451; called by muse, mutect2, varscan2
- ABHD1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV99574592; called by muse, mutect2
- ABHD12 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs900106828; called by muse, mutect2
- ABHD17A | c.661G>A p.A221T (on ENST00000292577 / NM_001130111.2; = p.A272T on NM_031213.4) | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.871); catalogued as COSV99171336; called by muse, mutect2
- ABHD6 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241505909; called by muse, mutect2, varscan2
- ABI3BP | c.2483G>A p.S828N | Missense Mutation (SNP) | VAF 247/528 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs745918552; called by muse, mutect2, varscan2
- ABL1 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 163/437 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); catalogued as rs140320313; called by muse, mutect2, varscan2
- ABL2 | c.2924C>T p.P975L (on ENST00000502732 / NM_007314.4; = p.P960L on NM_005158.5) | Missense Mutation (SNP) | VAF 204/465 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746054653; called by muse, mutect2, varscan2
- AC004593.2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765588; called by muse, mutect2
- AC005697.1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 124/330 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs535087199; called by muse, varscan2
- AC011005.1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 272/776 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs540175247, COSV71956058; called by muse, mutect2, varscan2
- AC093323.1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs896108495; called by muse, varscan2
- AC093525.2 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 149/346 reads (43%) | PolyPhen benign (0.003); catalogued as rs1476986826, COSV99565477; called by muse, varscan2
- ACAA2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV53271010; called by muse, mutect2, varscan2
- ACADS | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 186/370 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747339462, CM035802; called by muse, mutect2
- ACE | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52012879; called by muse, mutect2, varscan2
- ACSL5 | c.1615G>A p.D539N (on ENST00000354273; = p.D595N on NM_016234.3) | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749931911, COSV61130657; called by muse, mutect2, varscan2
- ACSM2A | c.733G>A p.D245N (on ENST00000219054; = p.D166N on NM_001308169.2) | Missense Mutation (SNP) | VAF 104/116 reads (90%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.783); catalogued as rs1197928623, COSV54584142, COSV99524994; called by muse, mutect2, varscan2
- ACTA2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1060500133; ClinVar: uncertain significance; called by muse, mutect2
- ACTL10 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 184/525 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs766845585; called by muse, mutect2, varscan2
- ACTR8 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51637940; called by muse, mutect2, varscan2
- ACVR1 | c.1395+1G>A p.X465_splice | Splice Site (SNP) | VAF 83/222 reads (37%) | catalogued as COSV55117590; called by muse, mutect2, varscan2
- ADAM21 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99960770; called by muse, mutect2, varscan2
- ADAM28 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs377655974; called by muse, mutect2, varscan2
- ADAM8 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 38/579 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV69864972; called by muse, mutect2
- ADAMTS10 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 173/386 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.957); catalogued as COSV54358810; called by muse, mutect2
- ADAMTS13 | c.3626G>A p.G1209E | Missense Mutation (SNP) | VAF 23/477 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1554795846; called by muse, mutect2
- ADAMTS14 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs745561902; called by muse, mutect2, varscan2
- ADAMTS9 | c.5770C>T p.P1924S | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350009717; called by muse, mutect2, varscan2
- ADAMTS9 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55779408; called by muse, mutect2, varscan2
- ADAMTSL2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 138/446 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63203798; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 155/407 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318980556; called by muse, mutect2, varscan2
- ADARB1 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 146/422 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV62344476; called by muse, mutect2, varscan2
- ADCK2 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50783062, COSV50784008; called by muse, mutect2, varscan2
- ADCY9 | c.1664G>A p.G555D | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1399804998, COSV53579925; called by muse, mutect2, varscan2
- ADCY9 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 40/525 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769951663; called by muse, mutect2
- ADCYAP1R1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 178/400 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs374708368; called by muse, mutect2, varscan2
- ADGB | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58856191; called by muse, mutect2, varscan2
- ADGRB1 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1480959221; called by muse, mutect2, varscan2
- ADGRD1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs201661954; called by muse, mutect2, varscan2
- ADGRE3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs1166647173, COSV53730748; called by muse, mutect2, varscan2
- ADGRF4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51949913; called by muse, mutect2, varscan2
- ADGRF5 | c.3667G>A p.V1223I | Missense Mutation (SNP) | VAF 188/371 reads (51%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.52); catalogued as rs1225532020; called by muse, mutect2, varscan2
- ADGRF5 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV51940321; called by muse, mutect2
- ADGRG4 | c.5599G>A p.G1867R | Missense Mutation (SNP) | VAF 176/211 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54966625; called by muse, mutect2, varscan2
- ADGRV1 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 185/432 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); catalogued as CM0911267, COSV67987929; called by muse, mutect2, varscan2
- ADGRV1 | c.12224C>T p.T4075I | Missense Mutation (SNP) | VAF 115/406 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs751145746; called by muse, mutect2, varscan2
- AFAP1L2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1191746735; called by muse, mutect2, varscan2
- AGBL5 | c.2552G>A p.S851N | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as rs755038675; called by muse, mutect2, varscan2
- AGGF1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100462344; called by muse, mutect2, varscan2
- AGMAT | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 265/544 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1188948300; called by muse, mutect2
- AGRN | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 184/407 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs764702249; called by muse, mutect2
- AGRN | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 158/349 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101038779; called by muse, mutect2, varscan2
- AHCYL2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 150/558 reads (27%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs779001507; called by muse, mutect2, varscan2
- AHDC1 | c.2915G>A p.G972D | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs1260191265; called by muse, mutect2
- AHNAK | c.7615G>A p.V2539I | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142790754; called by muse, mutect2
- AHNAK2 | c.6758G>A p.G2253D | Missense Mutation (SNP) | VAF 182/507 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs371063695; called by muse, mutect2, varscan2
- AIP | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs536239840; called by muse, varscan2
- AKAP11 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1566276050; called by muse, mutect2, varscan2
- AKAP13 | c.6547G>A p.D2183N (on ENST00000394518 / NM_007200.5; = p.D2187N on NM_006738.6) | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs776441394; called by muse, mutect2, varscan2
- AKNA | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs770746845; called by muse, mutect2, varscan2
- AL645922.1 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.283); catalogued as rs975649470; called by muse, mutect2
- ALG12 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 205/459 reads (45%) | PolyPhen benign (0.081); catalogued as rs753389161, COSV100427172; called by muse, mutect2, varscan2
- ALKBH7 | c.504-1G>A p.X168_splice | Splice Site (SNP) | VAF 88/207 reads (43%) | catalogued as COSV55531938; called by muse, mutect2
- ALOX15 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 145/388 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541442; called by muse, mutect2, varscan2
- ALX4 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1287276795; called by muse, mutect2, varscan2
- AMH | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 52/642 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs768982663; called by muse, mutect2
- ANGPTL5 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238493657, COSV100527960; called by muse, mutect2
- ANK3 | c.10696C>T p.P3566S | Missense Mutation (SNP) | VAF 178/364 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.335); catalogued as rs768050877; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4291C>T p.L1431F | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51847125; called by muse, mutect2, varscan2
- ANKLE1 | c.1948C>T p.L650F (on ENST00000394458; = p.L596F on NM_152363.6) | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs779030725, COSV101082168; called by muse, mutect2, varscan2
- ANKMY1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 158/323 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1423953853; called by muse, mutect2, varscan2
- ANKRD30B | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs767020498; called by muse, mutect2, varscan2
- ANKRD37 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 146/306 reads (48%) | catalogued as rs768367964; called by muse, varscan2
- ANKRD54 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as rs1232758185; called by muse, mutect2, varscan2
- ANKUB1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 157/291 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV67168124, COSV67168205; called by muse, mutect2, varscan2
- ANO8 | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs899931873; called by muse, mutect2
- ANXA10 | c.401-1G>A p.X134_splice | Splice Site (SNP) | VAF 14/209 reads (7%) | catalogued as COSV63739859; called by muse, mutect2
- AOAH | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51735280; called by muse, mutect2
- AP2A1 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.929); catalogued as rs1341455840; called by muse, mutect2, varscan2
- AP3M1 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs747979202; called by muse, mutect2, varscan2
- AP4M1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 100/455 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1447839854; called by muse, mutect2, varscan2
- AP5Z1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 135/464 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1056631913; called by muse, mutect2, varscan2
- APOB | c.12025G>A p.V4009M | Missense Mutation (SNP) | VAF 192/415 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs140424976; called by muse, mutect2, varscan2
- ARC | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 188/580 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1262375538, COSV63078041; called by muse, varscan2
- ARHGAP21 | c.4871G>A p.S1624N | Missense Mutation (SNP) | VAF 31/473 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483903977; called by muse, mutect2
- ARHGAP24 | c.807-1G>A p.X269_splice (on ENST00000395184 / NM_001025616.3; = p.X176_splice on NM_031305.3) | Splice Site (SNP) | VAF 55/168 reads (33%) | catalogued as rs148824321; called by muse, mutect2, varscan2
- ARHGEF18 | c.1635C>T p.S545= (on ENST00000359920 / NM_001130955.2; = p.S441= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 78/207 reads (38%) | catalogued as rs1404434466; called by muse, mutect2, varscan2
- ARHGEF25 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1434570805; called by muse, mutect2
- ARHGEF5 | c.3205G>A p.V1069I | Missense Mutation (SNP) | VAF 60/588 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs749717858; called by muse, mutect2
- ARL6IP6 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100424017; called by muse, mutect2
- ARMC5 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 32/463 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1235827929; called by muse, mutect2
- ARMC8 | c.1106G>A p.G369E (on ENST00000469044 / NM_001363941.2; = p.G355E on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV61768716; called by muse, mutect2, varscan2
- ARSD | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs759226882; called by muse, mutect2, varscan2
- ARSH | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1252317392; called by muse, mutect2, varscan2
- ARSJ | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 156/400 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs756095959; called by muse, mutect2, varscan2
- ART1 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 50/670 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765406319, COSV51707536; called by muse, mutect2
- ASAH1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190139418; called by muse, mutect2, varscan2
- ASCL5 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 191/401 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs923401269; called by muse, mutect2, varscan2
- ASXL1 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 136/490 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs1183315960, COSV60105348; called by muse, varscan2
- ASXL1 | c.4495G>A p.V1499M | Missense Mutation (SNP) | VAF 181/408 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.577); catalogued as rs761827265; called by muse, mutect2, varscan2
- ASXL3 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV99325210; called by muse, mutect2
- ASXL3 | c.3470G>A p.G1157D | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1352935416; called by muse, mutect2
- ATAD2 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 152/359 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1347687620; called by muse, mutect2, varscan2
- ATF6 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs11799951; called by muse, mutect2
- ATG2A | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV65966578; called by muse, mutect2
- ATG4D | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 187/332 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs756130278; called by muse, mutect2, varscan2
- ATG9A | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 40/493 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1345757281; called by muse, mutect2
- ATM | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs76379269; called by muse, mutect2
- ATP5PF | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 29/388 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.494); catalogued as rs1191457514; called by muse, mutect2
- ATP8A2 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761451341; called by muse, mutect2, varscan2
- ATP8A2 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1435163235; called by muse, mutect2, varscan2
- ATXN2L | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 150/323 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1269710768; called by muse, mutect2, varscan2
- ATXN7L2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 134/439 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as rs770910741; called by muse, mutect2, varscan2
- AUTS2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 240/719 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs1222966716; called by muse, mutect2, varscan2
- B3GNT7 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 32/621 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1447765254, COSV99805878; called by muse, mutect2
- BACE1 | c.566G>T p.R189M | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV57286439; called by muse, mutect2, varscan2
- BAD | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 214/503 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as rs201046961; called by muse, mutect2, varscan2
- BAHCC1 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 164/523 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as rs1234842403; called by muse, varscan2
- BAHCC1 | c.4510C>T p.L1504F | Missense Mutation (SNP) | VAF 111/367 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs543520686; called by muse, mutect2, varscan2
- BAIAP2L2 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs780264497; called by muse, mutect2, varscan2
- BCAN | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 165/397 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1263833249; called by muse, mutect2, varscan2
- BCAN | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 248/478 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1284107409; called by muse, mutect2, varscan2
- BCAS1 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1001879103; called by muse, mutect2
- BCAT1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 137/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678889; called by muse, mutect2, varscan2
- BCHE | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 31/343 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745482363; called by muse, mutect2
- BCKDHB | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM126891; called by muse, mutect2, varscan2
- BCL2L1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV56968968; called by muse, mutect2
- BCL2L12 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.58); catalogued as rs138111341; called by muse, mutect2, varscan2
- BCL9 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 43/557 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782367122; called by muse, mutect2
- BCOR | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as COSV60719321; called by muse, mutect2, varscan2
- BCR | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 201/395 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1379784513; called by muse, mutect2, varscan2
- BDP1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1275025061; called by muse, mutect2
- BHLHE40 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as rs756156275; called by muse, mutect2, varscan2
- BICD1 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 201/432 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); catalogued as COSV55688153; called by muse, mutect2, varscan2
- BICRAL | c.2188G>A p.V730I | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs771291808; called by muse, mutect2
- BIRC3 | c.1622-1G>A p.X541_splice | Splice Site (SNP) | VAF 103/218 reads (47%) | catalogued as COSV54817668; called by muse, mutect2, varscan2
- BIRC6 | c.10837C>T p.L3613F | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428469; called by muse, mutect2
- BLK | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 137/284 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs768937409; called by muse, mutect2, varscan2
- BLMH | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as rs1173537308; called by muse, mutect2, varscan2
- BMP2K | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs1484364480; called by muse, mutect2, varscan2
- BMPR2 | c.3067G>A p.G1023S | Missense Mutation (SNP) | VAF 136/363 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs1049284289; called by muse, mutect2, varscan2
- BPHL | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66742962; called by muse, mutect2
- BPI | c.772G>A p.E258K (on ENST00000262865; = p.E254K on NM_001725.3) | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53407454; called by muse, mutect2, varscan2
- BRAP | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 134/347 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRCA1 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 162/335 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV58789003; called by muse, mutect2, varscan2
- BRD3 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1439180366; called by muse, mutect2, varscan2
- BRINP1 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56300406; called by muse, mutect2, varscan2
- BRPF1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 180/432 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57408629; called by muse, mutect2, varscan2
- BST1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1252997098; called by muse, mutect2, varscan2
- BTBD10 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs113696304; called by muse, mutect2, varscan2
- BTBD17 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1481406178; called by muse, mutect2
- BTBD7 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as rs774086947; called by muse, mutect2
- C10orf71 | c.3494G>A p.R1165K | Missense Mutation (SNP) | VAF 216/396 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV60510873; called by muse, mutect2, varscan2
- C11orf97 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 160/338 reads (47%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.971); catalogued as rs1405555081; called by muse, mutect2, varscan2
- C12orf40 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61131215; called by muse, mutect2, varscan2
- C16orf96 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 213/458 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1052772599; called by muse, mutect2, varscan2
- C1QTNF1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1381966945; called by muse, mutect2
- C1orf54 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as rs1389480150; called by muse, mutect2, varscan2
- C1orf87 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 176/440 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1194387370; called by muse, mutect2, varscan2
- C2CD2L | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 144/331 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs768428400; called by muse, mutect2, varscan2
- C3orf56 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 124/258 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as rs755960469; called by muse, mutect2, varscan2
- C6orf132 | c.3292G>A p.G1098S | Missense Mutation (SNP) | VAF 39/617 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1451374225; called by muse, mutect2
- C8orf33 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 152/429 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs748190702; called by muse, mutect2, varscan2
- C9 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 158/363 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs182243824, COSV54677642; called by muse, mutect2, varscan2
- C9orf57 | c.377G>A p.C126Y (on ENST00000377024 / NM_001371610.1; = p.C104Y on NM_001128618.2) | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65462920; called by muse, mutect2, varscan2
- CACHD1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as rs12044906; called by muse, mutect2, varscan2
- CACNA1S | c.5473G>A p.V1825M | Missense Mutation (SNP) | VAF 189/442 reads (43%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.994); catalogued as COSV62938891; called by muse, mutect2, varscan2
- CACNA2D4 | c.3309G>A p.E1103= | Splice Region (SNP) | VAF 241/484 reads (50%) | catalogued as rs1253613757, COSV99765652; called by muse, mutect2, varscan2
- CALHM1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs754905270; called by muse, mutect2, varscan2
- CALML4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 186/372 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776462687, COSV61205841; called by muse, varscan2
- CAMK4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV56679945; called by muse, varscan2
- CAMSAP2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 148/325 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1287929408; called by muse, mutect2, varscan2
- CAMSAP2 | c.718C>T p.P240S (on ENST00000236925 / NM_001297707.2; = p.P229S on NM_203459.3) | Missense Mutation (SNP) | VAF 162/377 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52671459; called by muse, mutect2, varscan2
- CAMSAP2 | c.2656G>A p.G886R (on ENST00000236925 / NM_001297707.2; = p.G875R on NM_203459.3) | Missense Mutation (SNP) | VAF 154/308 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV52666633; called by muse, mutect2, varscan2
- CAMTA1 | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as rs1470229348, COSV57912955; called by muse, mutect2
- CAPN14 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1275823094; called by muse, mutect2
- CAPN15 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 27/564 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1007561610; called by muse, mutect2
- CAPN3 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV58818926; called by muse, mutect2
- CAPN5 | c.823G>A p.V275M (on ENST00000456580; = p.V235M on NM_004055.5) | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1555041526, COSV53688085; called by muse, mutect2
- CAPS | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 31/509 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.269); catalogued as rs1419696359; called by muse, mutect2
- CAPS2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99060224; called by muse, mutect2, varscan2
- CARD6 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99620467, COSV99621456; called by muse, mutect2, varscan2
- CARNMT1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 166/440 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1490236133; called by muse, varscan2
- CASKIN1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 337/699 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs778233282; called by muse, mutect2, varscan2
- CASP4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 164/403 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67744951; called by muse, mutect2, varscan2
- CASZ1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 45/540 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV59741368; called by muse, mutect2
- CAT | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99573044; called by muse, mutect2, varscan2
- CATSPERB | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs1482335740; called by muse, mutect2, varscan2
- CATSPERB | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 170/343 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764572295; called by muse, mutect2, varscan2
- CATSPERG | c.2678C>T p.T893I | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV53054604; called by muse, varscan2
- CATSPERG | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 165/344 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99287077; called by muse, varscan2
- CBLC | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751768100; called by muse, mutect2, varscan2
- CBX7 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs1311854513; called by muse, mutect2, varscan2
- CC2D2A | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1348227304; called by muse, mutect2
- CCDC157 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1004947996; called by muse, mutect2, varscan2
- CCDC158 | c.2873G>A p.S958N | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.215); catalogued as COSV66355471; called by muse, mutect2
- CCDC159 | c.489C>T p.L163= | Splice Region (SNP) | VAF 17/376 reads (5%) | catalogued as COSV52258634; called by muse, mutect2
- CCDC168 | c.20090C>T p.T6697I | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.415); catalogued as COSV59425747; called by muse, mutect2
- CCDC180 | c.4813G>A p.A1605T | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV63834163; called by muse, mutect2, varscan2
- CCDC6 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV54057756; called by muse, mutect2, varscan2
- CCDC61 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs770957740; called by muse, mutect2, varscan2
- CCDC78 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 164/343 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1440693595; called by muse, varscan2
- CCDC80 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs985075515; called by muse, mutect2
- CCDC86 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 42/591 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs758249733; called by muse, mutect2
- CCHCR1 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 210/558 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs140284482; called by muse, mutect2, varscan2
- CCIN | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 115/847 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs756009275; called by muse, mutect2, varscan2
- CCR8 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 155/388 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300357681, COSV58337917; called by muse, mutect2, varscan2
- CD163L1 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 33/491 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs983471052, COSV100550112, COSV58023500; called by muse, mutect2
- CD163L1 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 184/396 reads (46%) | catalogued as rs1270140389; called by muse, mutect2, varscan2
- CD2BP2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs767481614; called by muse, mutect2, varscan2
- CD300LF | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 184/426 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV56897524; called by muse, mutect2, varscan2
- CD6 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1415521882, COSV104400892; called by muse, mutect2
- CD6 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 26/461 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57836027; called by muse, mutect2
- CDC16 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV52960835; called by muse, mutect2, varscan2
- CDC42BPA | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 149/289 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62009056; called by muse, mutect2, varscan2
- CDC42BPG | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 167/411 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61347486; called by muse, mutect2, varscan2
- CDCP1 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 144/492 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV56108564; called by muse, mutect2, varscan2
- CDCP2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs1224911236; called by muse, mutect2, varscan2
- CDH11 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 167/390 reads (43%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); catalogued as COSV51762172; called by muse, mutect2, varscan2
- CDH23 | c.8101C>T p.P2701S | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as rs1441899315; called by muse, mutect2
- CDHR5 | c.1835G>A p.G612E (on ENST00000358353 / NM_001171968.2; = p.G618E on NM_021924.5) | Missense Mutation (SNP) | VAF 107/771 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV57642998; called by muse, mutect2, varscan2
- CDK10 | c.955G>A p.E319K (on ENST00000353379 / NM_052988.5; = p.E248K on NM_052987.4) | Missense Mutation (SNP) | VAF 155/289 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs760259251; called by muse, mutect2, varscan2
- CDK12 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.637); catalogued as rs1452240517; called by muse, mutect2
- CDK13 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 143/237 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1255656611; called by muse, mutect2, varscan2
- CDK3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs775227568; called by muse, mutect2, varscan2
- CDK6 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV56005665; called by muse, mutect2, varscan2
- CDON | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs372823373; called by muse, mutect2, varscan2
- CEACAM3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 182/345 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1555827515; called by muse, mutect2, varscan2
- CELSR1 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 29/506 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1485085339, COSV99418782; called by muse, mutect2
- CEMIP | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1247601171; called by muse, mutect2
- CEMP1 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53550902; called by muse, mutect2
- CENPF | c.7897G>A p.A2633T | Missense Mutation (SNP) | VAF 211/466 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100871634; called by muse, mutect2, varscan2
- CEP126 | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs150274963; called by muse, mutect2, varscan2
- CEP128 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 38/448 reads (8%) | catalogued as COSV55371576; called by muse, mutect2
- CEP250 | c.4202G>A p.R1401K | Missense Mutation (SNP) | VAF 42/527 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV100698664; called by muse, mutect2
- CERS2 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1036369299; called by muse, mutect2
- CERT1 | c.2182C>G p.R728G (on ENST00000405807 / NM_001130105.1; = p.R600G on NM_005713.3) | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655779; called by muse, mutect2, varscan2
- CFAP44 | c.2240C>T p.T747I | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs987477229; called by muse, mutect2, varscan2
- CFAP65 | c.344C>T p.T115I (on ENST00000341552 / NM_194302.4; = p.T50I on NM_152389.4) | Missense Mutation (SNP) | VAF 139/272 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs1337523254; called by muse, mutect2, varscan2
- CFAP74 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV54571826; called by muse, mutect2, varscan2
- CFAP94 | c.583G>A p.A195T (on ENST00000320267 / NM_001352064.2; = p.A201T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs1227230173; called by muse, mutect2, varscan2
- CFH | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV62777369; called by muse, mutect2
- CFHR4 | c.308C>T p.S103F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_001201550.3) | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as rs1418071957, COSV52227339; called by muse, mutect2
- CHCHD5 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1439638137, COSV100260927; called by muse, mutect2
- CHD6 | c.6965C>T p.A2322V | Missense Mutation (SNP) | VAF 173/342 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs754820590; called by muse, mutect2, varscan2
- CHD7 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 23/596 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.068); catalogued as COSV71115751; called by muse, mutect2
- CHD7 | c.3347A>G p.K1116R | Missense Mutation (SNP) | VAF 253/493 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs750214154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.4982G>A p.G1661D (on ENST00000646647 / NM_001170629.2; = p.G1382D on NM_020920.4) | Missense Mutation (SNP) | VAF 164/324 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63219173; called by muse, mutect2, varscan2
- CHL1 | c.2056G>A p.V686I (on ENST00000397491 / NM_001253387.1; = p.V702I on NM_006614.4) | Missense Mutation (SNP) | VAF 164/314 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1305736477; called by muse, mutect2, varscan2
- CHRM2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57777228; called by muse, mutect2, varscan2
- CHRNA4 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 215/484 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs1435870435; called by muse, mutect2, varscan2
- CHRNA7 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180739; called by muse, mutect2
- CHST14 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 152/498 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1354036515, COSV60379096; called by muse, mutect2, varscan2
- CIC | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 227/429 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1568486138; called by muse, mutect2, varscan2
- CIC | c.4045G>A p.V1349I | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV50640263; called by muse, mutect2, varscan2
- CIT | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV55881496; called by muse, mutect2, varscan2
- CLASP1 | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1337033275; called by muse, mutect2, varscan2
- CLCN7 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99247093; called by muse, mutect2, varscan2
- CLEC18B | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 58/645 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as rs1454759976; called by muse, mutect2
- CLEC4M | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 149/303 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99940374; called by muse, mutect2, varscan2
- CLMN | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); catalogued as rs1566863190; called by muse, mutect2, varscan2
- CLMN | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs1238577004; called by muse, mutect2, varscan2
- CLTA | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.98); catalogued as rs779488340; called by muse, mutect2, varscan2
- CLTA | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 23/544 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99643637; called by muse, mutect2
- CLTCL1 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 186/368 reads (51%) | catalogued as rs371582873; called by muse, mutect2, varscan2
- CLVS1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs202247798, COSV57972230; called by muse, mutect2, varscan2
- CNGB1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.267); catalogued as rs1213983177, COSV51904227; called by muse, mutect2, varscan2
- CNTN4 | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs770392035, COSV61868002; called by muse, mutect2, varscan2
- CNTNAP1 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 214/462 reads (46%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.835); catalogued as rs1257297280; called by muse, mutect2, varscan2
- COASY | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs775808304; called by muse, mutect2, varscan2
- COG6 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775580766; called by muse, mutect2, varscan2
- COG8 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 166/441 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as rs1482733741; called by muse, mutect2, varscan2
- COL12A1 | c.8324C>T p.P2775L | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs888653396, COSV59390765; called by muse, mutect2, varscan2
- COL1A1 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV56808842; called by muse, varscan2
- COL1A2 | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 60/527 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99798941; called by muse, mutect2, varscan2
- COL24A1 | c.2681G>A p.G894D | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774123402, COSV65314127; called by muse, mutect2, varscan2
- COL28A1 | c.124+1G>A p.X42_splice | Splice Site (SNP) | VAF 96/306 reads (31%) | catalogued as rs1177880580; called by muse, mutect2, varscan2
- COL3A1 | c.3472G>A p.G1158S | Missense Mutation (SNP) | VAF 153/402 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1412727, COSV100482397; called by muse, mutect2, varscan2
- COL4A1 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 259/518 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148781420; called by muse, mutect2, varscan2
- COL4A5 | c.3553G>A p.G1185S | Missense Mutation (SNP) | VAF 115/143 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1353480777; called by muse, mutect2, varscan2
- COL4A5 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 147/167 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs757653472, CM1310548; called by muse, mutect2, varscan2
- COL7A1 | c.2710+1G>A p.X904_splice | Splice Site (SNP) | VAF 91/249 reads (37%) | catalogued as CS095167; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 139/286 reads (49%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs376503129; called by muse, mutect2, varscan2
- COMP | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 55/529 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM1410538, HM080088; called by muse, mutect2, varscan2
- COPG1 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100135229; called by muse, mutect2
- COPRS | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as rs1352848699; called by muse, mutect2, varscan2
- CPEB2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT deleterious, low confidence (0); catalogued as rs1232299376; called by muse, mutect2, varscan2
- CPNE7 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 134/343 reads (39%) | catalogued as COSV52015633; called by muse, mutect2, varscan2
- CPSF1 | c.2869G>A p.G957S | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782338628; called by muse, mutect2, varscan2
- CRB1 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV100957607, COSV66332650; called by muse, mutect2, varscan2
- CREB1 | c.689G>A p.G230E (on ENST00000432329 / NM_134442.5; = p.G216E on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753817619; called by muse, mutect2, varscan2
- CREBBP | c.6160C>T p.P2054S | Missense Mutation (SNP) | VAF 187/375 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV52131848; called by muse, varscan2
- CRISP2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs754988764; called by muse, varscan2
- CRPPA | c.1274G>A p.S425N (on ENST00000407010 / NM_001368197.1; = p.S375N on NM_001101417.4) | Missense Mutation (SNP) | VAF 128/362 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1337797656; called by muse, mutect2, varscan2
- CSF2RA | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 44/507 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as rs1429016805; called by muse, mutect2
- CSF3R | c.2342C>T p.T781I | Missense Mutation (SNP) | VAF 59/645 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1435148414; called by muse, mutect2
- CSGALNACT2 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs986735443, COSV65676185; called by muse, mutect2
- CSMD2 | c.6497G>A p.G2166D | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53971478; called by muse, mutect2
- CSMD3 | c.4472C>T p.P1491L (on ENST00000297405 / NM_001363185.1; = p.P1387L on NM_052900.3) | Missense Mutation (SNP) | VAF 144/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1489502163; called by muse, mutect2, varscan2
- CSNK2A1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs1225143921; called by muse, mutect2, varscan2
- CSPG5 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 255/535 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53133133; called by muse, mutect2, varscan2
- CSRNP1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949881028; called by muse, mutect2, varscan2
- CST1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 191/440 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs756782667; called by muse, mutect2, varscan2
- CTCF | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50549763; called by muse, mutect2
- CTDP1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 301/629 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs762885419; called by muse, mutect2, varscan2
- CTNNA2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 35/410 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as rs765394694, COSV100561245, COSV58152576; called by muse, mutect2
- CTNS | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110323; called by muse, mutect2, varscan2
- CTSS | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV64566149; called by muse, mutect2, varscan2
- CUL7 | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54820119; called by muse, mutect2, varscan2
- CUTC | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs920986260, COSV65081769; called by muse, mutect2
- CWF19L2 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99980250; called by muse, mutect2, varscan2
- CYB5D2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 148/408 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV100028919; called by muse, mutect2, varscan2
- CYP26B1 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 177/525 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs377154115; called by muse, mutect2, varscan2
- CYP26B1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV50012203; called by muse, varscan2
- CYP2A7 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs754459090; called by muse, mutect2
- CYP2S1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 189/370 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as rs976154000; called by muse, mutect2, varscan2
- CYP2W1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 236/753 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs141228662; called by muse, mutect2, varscan2
- CYP4A22 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 269/536 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53738432; called by muse, mutect2, varscan2
- DAAM1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 155/347 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62839720; called by muse, mutect2, varscan2
- DBP | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 211/485 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs998686655; called by muse, mutect2, varscan2
- DCAF1 | c.3755T>C p.I1252T | Missense Mutation (SNP) | VAF 226/436 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV60047030; called by muse, mutect2, varscan2
- DCAF12L1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 225/234 reads (96%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV64422471; called by muse, mutect2, varscan2
- DCAF16 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 205/418 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1454777841; called by muse, mutect2, varscan2
- DCDC1 | c.3944G>A p.G1315E (on ENST00000597505 / NM_001367979.1; = p.G422E on NM_020869.3) | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs572968052; called by muse, mutect2, varscan2
- DCT | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100986235; called by muse, mutect2
- DCTN3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 147/612 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1481861771; called by muse, mutect2, varscan2
- DDI2 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as rs1453273114, COSV101416143; called by muse, mutect2
- DDX43 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317618650; called by muse, mutect2
- DDX54 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 36/601 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs1457396498; called by muse, mutect2
- DDX54 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 195/425 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1055555413; called by muse, mutect2, varscan2
- DENND1A | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 235/490 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as COSV65349538; called by muse, mutect2, varscan2
- DENND2A | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 37/806 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV52058018; called by muse, mutect2
- DENND3 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 226/420 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs754247305; called by muse, varscan2
- DENND4B | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 105/251 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100768333, COSV63410780; called by muse, mutect2, varscan2
- DGKE | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1235326725; called by muse, mutect2, varscan2
- DGKI | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 197/548 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs975497755; called by muse, varscan2
- DGKZ | c.2057C>T p.S686F (on ENST00000454345 / NM_001105540.2; = p.S498F on NM_003646.4) | Missense Mutation (SNP) | VAF 23/317 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV58988293; called by muse, mutect2
- DHRS9 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59141774; called by muse, mutect2, varscan2
- DHX57 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1004526810; called by muse, mutect2, varscan2
- DHX8 | c.2999G>A p.G1000D | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV52257001; called by muse, mutect2, varscan2
- DIAPH1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 180/505 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1457366616; called by muse, varscan2
- DIS3 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66707160; called by muse, mutect2
- DIS3L2 | c.2551C>T p.L851F | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1060503033, COSV56050880; ClinVar: uncertain significance; called by muse, mutect2
- DLG2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV101072881; called by muse, mutect2
- DLGAP1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV59790748; called by muse, mutect2
- DLGAP4 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 144/413 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs144693579; called by muse, mutect2, varscan2
- DLL1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1185776829; called by muse, mutect2, varscan2
- DMPK | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 194/405 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV52182925; called by muse, mutect2, varscan2
- DMRTC2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.813); catalogued as rs782716976, COSV54185770; called by muse, mutect2
- DMXL2 | c.8863G>A p.E2955K | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs1193345361; called by muse, mutect2
- DNAH1 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs762346571; called by muse, mutect2, varscan2
- DNAH10 | c.7442C>T p.P2481L (on ENST00000409039; = p.P2420L on NM_207437.3) | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs746137612; called by muse, mutect2
- DNAH5 | c.8165G>A p.R2722K | Missense Mutation (SNP) | VAF 105/147 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54203956, COSV54217724; called by muse, mutect2, varscan2
- DNAH6 | c.8431G>A p.V2811I | Missense Mutation (SNP) | VAF 170/343 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs375086278; called by muse, mutect2, varscan2
- DNAH7 | c.6971G>A p.S2324N | Missense Mutation (SNP) | VAF 149/344 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs992819121; called by muse, mutect2, varscan2
- DNAH8 | c.6339G>A p.Q2113= | Splice Region (SNP) | VAF 47/162 reads (29%) | catalogued as COSV59451469; called by muse, mutect2, varscan2
- DNAH8 | c.6828G>A p.Q2276= | Splice Region (SNP) | VAF 20/276 reads (7%) | catalogued as COSV59427098; called by muse, mutect2
- DNAH9 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 179/380 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1175364860; called by muse, mutect2, varscan2
- DNAH9 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52347973; called by muse, mutect2, varscan2
- DNAJA1 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 26/742 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs961948955; called by muse, mutect2
- DNAJC22 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 30/467 reads (6%) | catalogued as rs1294102569; called by muse, mutect2
- DNMT3A | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs34191084; called by muse, mutect2, varscan2
- DOCK4 | c.5494C>T p.H1832Y | Missense Mutation (SNP) | VAF 159/575 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs374966318; called by muse, mutect2, varscan2
- DOCK4 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 118/451 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV70242438; called by muse, mutect2, varscan2
- DPF3 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 33/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63503440, COSV63503641; called by muse, mutect2
- DPYSL4 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs200150703, COSV58306767; called by muse, mutect2, varscan2
- DRAP1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 153/346 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs753718615; called by muse, mutect2, varscan2
- DRG1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58919199; called by muse, mutect2, varscan2
- DROSHA | c.3202C>T p.L1068F | Missense Mutation (SNP) | VAF 112/124 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV60775480, COSV60781351; called by muse, varscan2
- DSP | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 214/415 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs374283517; called by muse, mutect2, varscan2
- DUSP5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 258/532 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.515); catalogued as rs774167871; called by muse, varscan2
- DUSP5 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV63645505; called by muse, varscan2
- DVL1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV66679528; called by muse, mutect2
- DYNC1H1 | c.12425G>A p.G4142D | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100794156; called by muse, mutect2
- DYNC2I1 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs368651864, COSV68104959; called by muse, mutect2, varscan2
- DYRK1A | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 168/360 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs753226962; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYSF | c.5584G>A p.G1862R | Missense Mutation (SNP) | VAF 137/348 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1393147629; called by muse, mutect2, varscan2
- E2F5 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 134/259 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99809885; called by muse, mutect2, varscan2
- E4F1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 119/327 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199803798; called by muse, mutect2, varscan2
- ECD | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100881517; called by muse, mutect2, varscan2
- ECPAS | c.4145C>T p.T1382I | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs758346554; called by muse, mutect2, varscan2
- ECPAS | c.3767G>A p.G1256E | Missense Mutation (SNP) | VAF 183/361 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309372797; called by muse, mutect2, varscan2
- ECT2 | c.2242G>A p.E748K (on ENST00000392692 / NM_001349098.2; = p.E717K on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1336811997; called by muse, mutect2, varscan2
- EEF1A2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as rs1568994209; called by muse, mutect2
- EGFR | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 229/1444 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV51804378; called by muse, mutect2, varscan2
- EGFR | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 43/1186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51805944; called by muse, mutect2
- EGR4 | c.764C>T p.A255V (on ENST00000545030; = p.A152V on NM_001965.4) | Missense Mutation (SNP) | VAF 208/486 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1284243020; called by muse, mutect2, varscan2
- EIF2AK1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs774736402, COSV52236537; called by muse, mutect2, varscan2
- EIF2B3 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1456181265; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 214/405 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs761982631, COSV57517257; called by muse, mutect2, varscan2
- ELAC2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 170/405 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1398310385, COSV100568351; called by muse, mutect2, varscan2
- ELK3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 44/552 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs878882439; called by muse, mutect2
- ELMOD1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV99760521; called by muse, mutect2
- ELP4 | c.1187G>A p.R396H (on ENST00000350638; = p.R395H on NM_019040.5) | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs200155061; called by muse, mutect2, varscan2
- EMB | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 163/345 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); catalogued as rs750541683; called by muse, mutect2, varscan2
- EMC10 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100618449; called by muse, mutect2, varscan2
- EML2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as rs916564781; called by muse, mutect2
- EML6 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1258855038; called by muse, mutect2, varscan2
- ENAM | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 148/373 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as rs368423807; called by muse, mutect2, varscan2
- ENPP1 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs200239821, COSV62935669; called by muse, varscan2
- ENTPD1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 202/364 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1195301450; called by muse, mutect2, varscan2
- ENTPD4 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100652764, COSV100652820; called by muse, mutect2, varscan2
- EP300 | c.6488C>T p.P2163L | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1013716287; ClinVar: likely benign; called by muse, mutect2
- EPB42 | c.10+6C>T | Splice Region (SNP) | VAF 118/273 reads (43%) | catalogued as rs200354161; called by muse, mutect2, varscan2
- EPHA10 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs775096565; called by muse, mutect2, varscan2
- EPHA2 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 155/462 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs778657565; called by muse, mutect2, varscan2
- EPHA6 | c.2107C>T p.P703S (on ENST00000389672 / NM_001080448.3; = p.P95S on NM_173655.4) | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67561756; called by muse, mutect2
- EPHB2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 217/429 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs762351366; called by muse, mutect2, varscan2
- EPHB2 | c.2448G>A p.M816I (on ENST00000400191 / NM_001309193.2; = p.M817I on NM_004442.7) | Missense Mutation (SNP) | VAF 152/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs547041098; called by muse, mutect2, varscan2
- EPPK1 | c.4697C>T p.S1566F | Missense Mutation (SNP) | VAF 182/448 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782526891; called by muse, mutect2, varscan2
- EPRS1 | c.750+1G>A p.X250_splice | Splice Site (SNP) | VAF 15/191 reads (8%) | catalogued as rs867065160; called by muse, mutect2
- EPRS1 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293828261; called by muse, mutect2, varscan2
- EPX | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 212/468 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs189235341; called by muse, mutect2, varscan2
- ERC2 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1196207078, COSV55602734, COSV55615907; called by muse, mutect2
- ERCC2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 40/553 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1214025738; called by muse, mutect2
- ERMARD | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs367909990; called by muse, mutect2, varscan2
- ERN1 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV70500759; called by muse, mutect2
- ERN2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1387587019; called by muse, mutect2, varscan2
- ERV3-1 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754512409; called by muse, varscan2
- ERVFRD-1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100977399; called by muse, varscan2
- ERVMER34-1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.703); catalogued as rs1255540671; called by muse, mutect2, varscan2
- ERVV-2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 137/464 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs1173617947; called by muse, mutect2, varscan2
- ESPN | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 165/364 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs756669745; called by muse, mutect2, varscan2
- ETFBKMT | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55673286; called by muse, mutect2
- ETFDH | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172356159; called by muse, mutect2, varscan2
- ETV5 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 184/492 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV60501678; called by muse, mutect2, varscan2
- EVI5L | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs1327794517, COSV54487933; called by muse, mutect2
- EVPL | c.5645C>T p.A1882V | Missense Mutation (SNP) | VAF 216/429 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757437772; called by muse, mutect2, varscan2
- EXOSC4 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 171/452 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as rs1554763317; called by muse, mutect2, varscan2
- EXOSC8 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 94/176 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs535085627; called by muse, mutect2, varscan2
- EXPH5 | c.4534C>T p.P1512S | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.596); catalogued as rs775034564; called by muse, mutect2, varscan2
- EXPH5 | c.2171G>A p.G724D | Missense Mutation (SNP) | VAF 200/418 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1383584140; called by muse, mutect2, varscan2
- EXPH5 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as rs766525434, COSV99760735; called by muse, mutect2, varscan2
- EYA1 | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 36/425 reads (8%) | catalogued as COSV58165350; called by muse, mutect2
- EYA4 | c.1868C>T p.P623L (on ENST00000531901 / NM_001301013.1; = p.P617L on NM_004100.5) | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62054136; called by muse, mutect2
- F10 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 140/306 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs777432382; called by muse, varscan2
- FA2H | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as rs1477020267; called by muse, varscan2
- FAAP100 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 311/598 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100585603; called by muse, mutect2, varscan2
- FAM131A | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs978267365; called by muse, mutect2, varscan2
- FAM131B | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 254/813 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761262315; called by muse, mutect2, varscan2
- FAM131B | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV68125420; called by muse, mutect2
- FAM131C | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 33/596 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV65153419; called by muse, mutect2
- FAM151A | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 32/523 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1435809095; called by muse, mutect2
- FAM153CP | n.365-1G>A | Splice Site (SNP) | VAF 150/711 reads (21%) | catalogued as COSV101228637; called by muse, mutect2, varscan2
- FAM160A2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 200/430 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs150676373; called by muse, mutect2, varscan2
- FAM160B1 | c.2156G>A p.R719K | Missense Mutation (SNP) | VAF 19/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65089086; called by muse, mutect2
- FAM171A1 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 171/334 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1166569856; called by muse, mutect2, varscan2
- FAM186B | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 222/453 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV57720488; called by muse, mutect2, varscan2
- FAM47C | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1556332639, COSV100792250, COSV63723454; called by muse, mutect2, varscan2
- FAM83B | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 133/422 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139994975; called by muse, mutect2, varscan2
- FAM83F | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 243/443 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs769914565; called by muse, mutect2, varscan2
- FAM83H | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 46/694 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1554622324; called by muse, mutect2
- FAM83H | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601817; called by muse, varscan2
- FANCF | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 192/483 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59416514; called by muse, mutect2, varscan2
- FBRS | c.668C>T p.P223L (on ENST00000287468; = p.P743L on NM_001105079.3) | Missense Mutation (SNP) | VAF 301/637 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs1277811510; called by muse, mutect2, varscan2
- FBXL3 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62919286; called by muse, mutect2, varscan2
- FBXL4 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as rs1208827073; called by muse, mutect2, varscan2
- FBXO10 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1324355073; called by muse, mutect2, varscan2
- FBXO33 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 169/342 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as rs1404810837; called by muse, mutect2, varscan2
- FBXO8 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV67032440; called by muse, mutect2
- FBXW5 | c.1245G>A p.R415= | Splice Region (SNP) | VAF 166/382 reads (43%) | catalogued as rs144039568; called by muse, mutect2, varscan2
- FCHO1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 67/698 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs374443453; called by muse, mutect2
- FCN2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 112/292 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.038); catalogued as COSV52478727; called by muse, mutect2, varscan2
- FER1L5 | c.4692G>A p.M1564I (on ENST00000623019; = p.M1537I on NM_001293083.2) | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs772722211, COSV67605701; called by muse, mutect2, varscan2
- FGFR1 | c.944G>A p.G315E (on ENST00000447712 / NM_023110.3; = p.G313E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58341000; called by muse, varscan2
- FHAD1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1157784095; called by muse, mutect2, varscan2
- FHOD1 | c.2966C>T p.T989I | Missense Mutation (SNP) | VAF 229/477 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777791137; called by muse, mutect2, varscan2
- FHOD1 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 122/266 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422267033; called by muse, varscan2
- FKBP4 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 135/354 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs766142249, COSV50008992; called by muse, mutect2, varscan2
- FLG | c.11357C>T p.S3786F | Missense Mutation (SNP) | VAF 271/581 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100912513, COSV64252613; called by muse, varscan2
- FLG | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs763551148; called by muse, mutect2, varscan2
- FLOT2 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 125/283 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs772100503; called by muse, mutect2, varscan2
- FLT1 | c.3947G>A p.R1316K | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56731991; called by muse, mutect2
- FLT4 | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 162/374 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM126124; called by muse, mutect2, varscan2
- FLYWCH2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs747486710; called by muse, mutect2
- FMN2 | c.2788G>A p.G930S | Missense Mutation (SNP) | VAF 211/369 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.209); catalogued as rs748088983; called by muse, mutect2, varscan2
- FN1 | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775917038, COSV100116838; called by muse, mutect2, varscan2
- FNDC8 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754997508; called by muse, mutect2, varscan2
- FOXH1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 243/565 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs201165974; called by muse, mutect2, varscan2
- FOXH1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 237/522 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1043646541; called by muse, mutect2, varscan2
- FOXI1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs374176565; called by muse, mutect2, varscan2
- FOXJ3 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 47/643 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.202); catalogued as rs1351192002, COSV62365677; called by muse, mutect2
- FOXL2 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 142/476 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV57728109; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs1443982998; called by muse, mutect2
- FPR2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 159/400 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV60673394; called by muse, mutect2, varscan2
- FRAS1 | c.10663G>A p.E3555K | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53633841, COSV99346846; called by muse, mutect2, varscan2
- FSIP2 | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1413642378; called by muse, mutect2
- FUBP1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 113/257 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53937640; called by muse, mutect2, varscan2
- FUBP1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1434698050; called by muse, mutect2, varscan2
- FUT5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs766383156; called by muse, varscan2
- FUT5 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 210/498 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs1408512679; called by muse, varscan2
- FZD5 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 178/566 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as rs1254162407; called by muse, mutect2, varscan2
- GAA | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555600179, CM128382, COSV56411719; ClinVar: uncertain significance; called by muse, mutect2
- GABRR2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV68266205; called by muse, mutect2, varscan2
- GAK | c.3593C>T p.P1198L | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779077568, COSV58508466; called by muse, varscan2
- GANAB | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.14); catalogued as COSV60463986; called by muse, mutect2
- GAR1 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 67/722 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.992); catalogued as COSV56993620; called by muse, mutect2
- GARNL3 | c.2510C>T p.P837L | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.444); catalogued as rs762118972; called by muse, mutect2, varscan2
- GCKR | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 169/334 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs138402942; called by muse, mutect2, varscan2
- GDPD5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 37/606 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs1366712405; called by muse, mutect2
- GFPT2 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99518081; called by muse, mutect2
- GFY | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 211/577 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1233733191; called by muse, mutect2, varscan2
- GGA3 | c.382G>A p.E128K (on ENST00000537686 / NM_138619.4; = p.E95K on NM_014001.5) | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs912675113; called by muse, mutect2, varscan2
- GGN | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 225/421 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1325790631; called by muse, mutect2, varscan2
- GIGYF1 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 141/614 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1172433757; called by muse, varscan2
- GIMAP4 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 156/549 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1443456879; called by muse, mutect2, varscan2
- GJC3 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 59/569 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs778783132; called by muse, mutect2, varscan2
- GLI1 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs564218374; called by muse, mutect2, varscan2
- GLYR1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs1218184169; called by muse, mutect2
- GNE | c.1960G>A p.G654S (on ENST00000396594 / NM_001128227.3; = p.G623S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/400 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV100930087; called by muse, mutect2, varscan2
- GNE | c.1541G>A p.G514E (on ENST00000396594 / NM_001128227.3; = p.G483E on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/511 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64951261; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 206/1062 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1434408883; called by muse, varscan2
- GOLGA8M | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.699); catalogued as rs1433657548; called by muse, mutect2, varscan2
- GON4L | c.5932C>T p.P1978S | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1214140148; called by muse, mutect2
- GOT2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1428801837, COSV99803456; called by muse, mutect2
- GPAM | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs765572330; called by muse, mutect2, varscan2
- GPD2 | c.2041C>T p.L681F | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.111); catalogued as COSV60097845; called by muse, mutect2, varscan2
- GPR107 | c.1576C>T p.L526F (on ENST00000372406 / NM_001136557.2; = p.L478F on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/315 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100714688; called by muse, mutect2, varscan2
- GPR137C | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 142/298 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs763627535; called by muse, mutect2, varscan2
- GPR137C | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 142/307 reads (46%) | catalogued as rs867519635, COSV58704821; called by muse, mutect2, varscan2
- GPR180 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 128/259 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs1221402785; called by muse, mutect2, varscan2
- GPR39 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV61423373; called by muse, varscan2
- GPRIN2 | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 141/707 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555017506; called by muse, mutect2, varscan2
- GPRIN2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 106/580 reads (18%) | catalogued as rs1555019409; called by muse, mutect2, varscan2
- GRIK4 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 142/273 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs1335757866; called by muse, mutect2, varscan2
- GRIN2C | c.3137_3138insTCCGGAGCC p.E1048_L1049insPPE | In Frame Ins (INS) | VAF 173/375 reads (46%) | catalogued as COSV53109802; called by mutect2, pindel, varscan2
- GRIN3A | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1295344270; called by muse, mutect2
- GRIN3A | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1354502258; called by muse, mutect2, varscan2
- GRM1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 154/358 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs1279453638; called by muse, mutect2, varscan2
- GRM2 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 20/513 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1477920982, COSV99622344; called by muse, mutect2
- GSDMC | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149214871; called by muse, mutect2, varscan2
- GSS | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99404438; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 110/441 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1554532942, COSV57032460; called by muse, varscan2
- GTPBP1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 195/458 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99323043; called by muse, mutect2, varscan2
- GUCY2D | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 226/472 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as rs1475142231; called by muse, mutect2, varscan2
- GXYLT1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as rs747871804; called by muse, mutect2, varscan2
- H1-4 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 145/368 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as rs781197204; called by muse, mutect2, varscan2
- H2AC12 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 168/373 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1053911294, COSV63617377; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, mutect2, varscan2
- H4-16 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 166/370 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV100797598, COSV100797641; called by muse, mutect2, varscan2
- H6PD | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1209903921; called by muse, mutect2
- HAL | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764135653; called by muse, varscan2
- HAO2 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377849; called by muse, mutect2, varscan2
- HAS1 | c.1062G>A p.K354= | Splice Region (SNP) | VAF 284/548 reads (52%) | catalogued as rs552959486; called by muse, mutect2
- HAS1 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 188/412 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs945398316; called by muse, mutect2, varscan2
- HCFC1 | c.4234C>T p.P1412S | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as rs368933757; called by muse, mutect2, varscan2
- HCN2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 231/475 reads (49%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.04); catalogued as rs1287052088; called by muse, mutect2, varscan2
- HCN3 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62876447; called by muse, mutect2
- HDAC5 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs560931871; called by muse, mutect2, varscan2
- HDAC9 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 115/495 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV67769768; called by muse, mutect2, varscan2
- HDGF | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs750720441; called by muse, mutect2, varscan2
- HDHD5 | c.634C>T p.L212F (on ENST00000336737 / NM_033070.3; = p.L182F on NM_017829.5) | Missense Mutation (SNP) | VAF 173/444 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757532322, COSV50088144; called by muse, mutect2, varscan2
- HELLS | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 21/328 reads (6%) | catalogued as rs1330145415; called by muse, mutect2
- HELZ | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); catalogued as rs1197639514; called by muse, mutect2, varscan2
- HEMK1 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51750308; called by muse, varscan2
- HEPHL1 | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs891943528; called by muse, mutect2, varscan2
- HEPN1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.484); catalogued as rs1565335842; called by muse, mutect2, varscan2
- HERC1 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71248023; called by muse, mutect2
- HERPUD2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs764383809; called by muse, mutect2, varscan2
- HHLA2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs903815869; called by muse, mutect2
- HIC1 | c.944G>A p.G315E (on ENST00000322941 / NM_001098202.1; = p.G296E on NM_006497.4) | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs1440665971; called by muse, mutect2
- HIPK3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 161/322 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100305487; called by muse, mutect2, varscan2
- HIVEP3 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 162/426 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460785104; called by muse, mutect2, varscan2
- HIVEP3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 239/489 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs1395382508; called by muse, mutect2, varscan2
- HKDC1 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 38/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370167561; called by muse, mutect2
- HLTF | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV59500283; called by muse, mutect2, varscan2
- HMG20B | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 190/444 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as COSV53571930; called by muse, varscan2
- HMGCLL1 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767831751; called by muse, mutect2, varscan2
- HMOX1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99330559; called by muse, varscan2
- HMX3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 236/463 reads (51%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.037); catalogued as COSV63501965; called by muse, mutect2, varscan2
- HNRNPM | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 196/399 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249293106, COSV100335292, COSV57691959; called by muse, mutect2, varscan2
- HNRNPM | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 262/544 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs375484908; called by muse, varscan2
- HOMEZ | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62537857; called by muse, varscan2
- HOXA11 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 158/445 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50052881; called by muse, mutect2, varscan2
- HOXA7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 251/465 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766593338; called by muse, mutect2, varscan2
- HP | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1329086523; called by muse, mutect2, varscan2
- HRC | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53255644, COSV99417787; called by muse, mutect2, varscan2
- HRNR | c.2759G>A p.G920D | Missense Mutation (SNP) | VAF 255/586 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.099); catalogued as rs755328752; called by muse, mutect2, varscan2
- HSF2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.499); catalogued as rs1418385695; called by muse, mutect2, varscan2
- HSF2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs767805539; called by muse, mutect2, varscan2
- HSPA12B | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 182/498 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs1326857831; called by muse, varscan2
- HSPA1L | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); catalogued as rs779447554; called by muse, mutect2, varscan2
- HSPA8 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 151/400 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV57085599; called by muse, mutect2, varscan2
- HSPBAP1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 170/392 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748268421, COSV60242728; called by muse, mutect2, varscan2
- HSPG2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 192/358 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1388933414; called by muse, mutect2, varscan2
- HTR3B | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as rs1329330147; called by muse, mutect2
- HUNK | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99527876; called by muse, mutect2
- HYAL2 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 180/433 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.285); catalogued as rs782327523; called by muse, mutect2, varscan2
- HYDIN | c.12926C>T p.P4309L | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1455760595; called by muse, mutect2, varscan2
- IBSP | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs144185482; called by muse, mutect2, varscan2
- ID4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 188/360 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758123800; called by muse, varscan2
- IFITM2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 161/444 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1451585419; called by muse, mutect2
- IFNLR1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 199/410 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1286621504; called by muse, mutect2, varscan2
- IFRD2 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 154/347 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1553709621; called by muse, mutect2, varscan2
- IGF2R | c.2879G>A p.G960D | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV63629846; called by muse, mutect2
- IGFN1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs1335431765; called by muse, mutect2
- IGHV3OR16-13 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as rs769619522; called by muse, mutect2, varscan2
- IGSF22 | c.2557C>T p.P853S (on ENST00000319338; = p.P954S on NM_173588.4) | Missense Mutation (SNP) | VAF 223/488 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs776997419; called by muse, mutect2, varscan2
- IGSF8 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 43/594 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs1246751898; called by muse, mutect2
- IKBKB | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV60596147; called by muse, mutect2
- IL17C | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 169/419 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs757431231; called by muse, mutect2, varscan2
- IL17RA | c.1973G>A p.G658D | Missense Mutation (SNP) | VAF 188/553 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1293623909; called by muse, mutect2, varscan2
- IL17RD | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs772168853; called by muse, mutect2, varscan2
- IL1RL2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs1213740967; called by muse, mutect2
- IL1RN | c.250G>A p.G84R (on ENST00000409930 / NM_173842.3; = p.G66R on NM_000577.5) | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368461190; called by muse, mutect2, varscan2
- INAFM1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 150/355 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1315480957; called by muse, mutect2, varscan2
- INO80 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100732118, COSV62738497; called by muse, mutect2, varscan2
- INPP4A | c.2063G>A p.G688D (on ENST00000074304 / NM_001134224.1; = p.G649D on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50795996; called by muse, varscan2
- INPP5A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 137/273 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV61252104; called by muse, mutect2, varscan2
- INSL5 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 142/325 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV58788362; called by muse, mutect2, varscan2
- INSR | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM021104; called by muse, mutect2, varscan2
- INSYN2A | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 194/455 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.175); catalogued as rs1486536927; called by muse, mutect2, varscan2
- INTS5 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 126/365 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.655); catalogued as rs1454845375; called by muse, mutect2, varscan2
- IQANK1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 170/435 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1202967461; called by muse, mutect2, varscan2
- IQANK1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.383); catalogued as rs573906713; called by muse, mutect2
- IQCC | c.186G>A p.E62= | Splice Region (SNP) | VAF 100/291 reads (34%) | catalogued as rs1235120290; called by muse, mutect2, varscan2
- IQCC | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 152/467 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52210496; called by muse, mutect2, varscan2
- IQGAP1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 38/503 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs1251938861; called by muse, mutect2
- IRAK4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 125/327 reads (38%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV71210502; called by muse, mutect2, varscan2
- IRF2BP1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 168/503 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV56195383; called by muse, mutect2, varscan2
- IRF3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 160/427 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs377085289; called by muse, mutect2, varscan2
- IRGC | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs770570307; called by muse, mutect2, varscan2
- IRS4 | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100929419; called by muse, mutect2, varscan2
- ISG15 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 188/471 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.405); catalogued as rs745347132; called by muse, mutect2, varscan2
- ITGA10 | c.1794G>A p.R598= | Splice Region (SNP) | VAF 112/235 reads (48%) | catalogued as rs782448854; called by muse, mutect2, varscan2
- ITGA9 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs149951749; called by muse, mutect2, varscan2
- ITGAE | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV53990884; called by muse, mutect2, varscan2
- ITGB1 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100171630; called by muse, mutect2
- ITIH2 | c.738G>A p.K246= | Splice Region (SNP) | VAF 40/117 reads (34%) | catalogued as COSV64432997; called by muse, mutect2, varscan2
- ITIH5 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs540293946; called by muse, mutect2, varscan2
- ITPKB | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 188/424 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.115); catalogued as COSV55269772; called by muse, mutect2, varscan2
- JADE2 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1442375929; called by muse, mutect2
- JAK3 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV71687254; called by muse, mutect2, varscan2
- JHY | c.2240A>T p.E747V | Missense Mutation (SNP) | VAF 162/346 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV57076696; called by muse, mutect2, varscan2
- JPH3 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 148/392 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248822669; called by muse, varscan2
- KANSL2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs371581944; called by muse, mutect2, varscan2
- KATNIP | c.2891G>A p.G964D | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1440823150; called by muse, mutect2, varscan2
- KCNA1 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66837842; called by muse, mutect2, varscan2
- KCNA10 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs779800189, COSV63904481; called by muse, mutect2, varscan2
- KCNB2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73053110; called by muse, mutect2, varscan2
- KCNG2 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 204/538 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60266786; called by muse, mutect2, varscan2
- KCNH6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 214/435 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs756068734; called by muse, mutect2, varscan2
- KCNK5 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV100851937; called by muse, mutect2
- KCNQ2 | c.1681C>T p.P561S (on ENST00000359125 / NM_172107.4; = p.P533S on NM_004518.6) | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM165060; called by muse, mutect2, varscan2
- KCNQ4 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 176/380 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1458459083; called by muse, mutect2, varscan2
- KCNS3 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV58405297; called by muse, mutect2
- KCNU1 | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV101299132; called by muse, mutect2, varscan2
- KCNV2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66057086; called by muse, mutect2, varscan2
- KCP | c.1216C>T p.P406S (on ENST00000620378; = p.P463S on NM_001366122.1) | Missense Mutation (SNP) | VAF 216/661 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as rs771189428; called by muse, mutect2, varscan2
- KCTD13 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs1421044793; called by muse, mutect2
- KDM3B | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1275632112; called by muse, mutect2
- KDM6B | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 183/345 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs758603417; called by muse, mutect2, varscan2
- KIAA0232 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.344); catalogued as rs1029478990; called by muse, mutect2, varscan2
- KIAA1210 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 129/184 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1346879161, COSV68177298, COSV68177308; called by muse, mutect2, varscan2
- KIAA1549 | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 106/547 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777698134; called by muse, mutect2, varscan2
- KIAA1671 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as rs985085909; called by muse, mutect2
- KIF1A | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 148/387 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV57497438; called by muse, mutect2, varscan2
- KIF20B | c.4038G>A p.E1346= (on ENST00000371728 / NM_001284259.2; = p.E1306= on NM_016195.4) | Splice Region (SNP) | VAF 81/200 reads (41%) | catalogued as rs150098337; called by muse, mutect2, varscan2
- KIF20B | c.4097-1G>A p.X1366_splice (on ENST00000371728 / NM_001284259.2; = p.X1326_splice on NM_016195.4) | Splice Site (SNP) | VAF 51/139 reads (37%) | catalogued as COSV53304061; called by muse, mutect2, varscan2
- KIF21B | c.2731G>A p.A911T | Missense Mutation (SNP) | VAF 157/380 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs377123925, COSV59754573; called by muse, mutect2, varscan2
- KIF21B | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as rs1336478996; called by muse, mutect2
- KIF26B | c.3611G>A p.S1204N | Missense Mutation (SNP) | VAF 54/737 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833314; called by muse, mutect2
- KIF3A | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1388938837; called by muse, mutect2, varscan2
- KIFC2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1279090223; called by muse, mutect2
- KIFC3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 328/653 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.994); catalogued as rs1555623884; called by muse, mutect2, varscan2
- KMT2B | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs374066966; called by muse, mutect2, varscan2
- KMT2B | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as rs374176981; called by muse, mutect2, varscan2
- KMT2C | c.4007C>T p.S1336F | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV51458943; called by muse, mutect2, varscan2
- KMT2D | c.10606C>T p.R3536C | Missense Mutation (SNP) | VAF 161/353 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD114134, COSV56428871; called by muse, mutect2, varscan2
- KRT16 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 225/449 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs765533099; called by muse, mutect2, varscan2
- KRT2 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 220/473 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as rs201743641; called by muse, mutect2, varscan2
- KRT20 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 178/534 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as rs769869953; called by muse, mutect2, varscan2
- KRT32 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 157/287 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs933069187; called by muse, mutect2, varscan2
- KRT6B | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as rs1360812915; called by muse, mutect2, varscan2
- KRT72 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1258616553, COSV53374170; called by muse, mutect2, varscan2
- KRT73 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 133/371 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1190249282; called by muse, mutect2, varscan2
- KRT76 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs748842366, COSV60121165; called by muse, mutect2, varscan2
- KRT85 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 139/281 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57736881; called by muse, mutect2, varscan2
- KRTAP10-1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 184/468 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as rs1199760889; called by muse, mutect2, varscan2
- KRTAP10-3 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 50/730 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV59951897, COSV59955836; called by muse, mutect2
- KRTAP16-1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 212/513 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1384179132; called by muse, mutect2, varscan2
- KRTAP24-1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 228/407 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as rs746549598; called by muse, mutect2, varscan2
- KRTAP4-11 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 348/843 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs778010463, COSV101194925; called by muse, mutect2, varscan2
- KRTAP5-6 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 76/619 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs561591624; called by muse, mutect2, varscan2
- L1CAM | c.2289G>A p.W763* | Nonsense Mutation (SNP) | VAF 30/342 reads (9%) | catalogued as rs1557091014; called by muse, mutect2
- LACTB | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 226/500 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.035); catalogued as rs1334088859, COSV99978999; called by muse, mutect2, varscan2
- LAIR1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 50/714 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs778203426, COSV100479992; called by muse, mutect2
- LAMB4 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs753900276, COSV99225004; called by muse, mutect2, varscan2
- LAMC1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV51141086; called by muse, mutect2
- LAMC2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.941); catalogued as rs367738116; called by muse, mutect2, varscan2
- LAMC3 | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs151159947; called by muse, varscan2
- LAMP1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 228/467 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs1312058594; called by muse, mutect2, varscan2
- LARP1 | c.2444C>T p.P815L (on ENST00000518297 / NM_033551.3; = p.P738L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs1186311651; called by muse, mutect2, varscan2
- LBX1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 245/528 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1178332623; called by muse, mutect2, varscan2
- LCE1E | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 221/536 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1167796572, COSV64219542; called by muse, mutect2, varscan2
- LCOR | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 161/308 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs774593262; called by muse, mutect2, varscan2
- LCOR | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs1244894429; called by muse, mutect2, varscan2
- LCP1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 134/408 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59941203, COSV59943773; called by muse, mutect2, varscan2
- LENG8 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 183/429 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs1237501166; called by muse, mutect2, varscan2
- LGR4 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs1330154221; called by muse, mutect2, varscan2
- LGR6 | c.1441C>T p.P481S (on ENST00000367278 / NM_001017403.1; = p.P429S on NM_021636.3) | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs146224606; called by muse, mutect2, varscan2
- LHX9 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 184/448 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV61331241; called by muse, mutect2, varscan2
- LIF | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs771820759; called by muse, mutect2, varscan2
- LILRA1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 35/686 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as rs774879937; called by muse, mutect2
- LILRA2 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 265/894 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV99252942; called by muse, varscan2
- LILRB3 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 200/1135 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV54434230, COSV99557792; called by muse, varscan2
- LIM2 | c.278C>T p.S93F (on ENST00000596399 / NM_001161748.2; = p.S135F on NM_030657.4) | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs1267227291, COSV55741323; called by muse, mutect2, varscan2
- LIMD1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs896057068; called by muse, varscan2
- LIN7A | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV54023381; called by muse, mutect2, varscan2
- LLGL2 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 37/487 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV51341622, COSV51343445; called by muse, mutect2
- LMLN2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT deleterious (0.02); catalogued as rs1381387984; called by muse, mutect2
- LMO7 | c.620G>A p.G207D (on ENST00000357063; = p.G222D on NM_005358.5) | Missense Mutation (SNP) | VAF 169/373 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309512704, COSV100414024; called by muse, mutect2, varscan2
- LMOD1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 230/553 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV66172842; called by muse, mutect2, varscan2
- LPAR5 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as rs1235079634; called by muse, mutect2
- LPO | c.1520-1G>A p.X507_splice | Splice Site (SNP) | VAF 19/220 reads (9%) | catalogued as rs1156797605; called by muse, mutect2
- LRFN1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 183/448 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as rs780731720; called by muse, mutect2, varscan2
- LRFN2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 218/457 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1216726423; called by muse, mutect2, varscan2
- LRFN3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 198/504 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912468422, COSV55817736; called by muse, mutect2, varscan2
- LRG1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 210/441 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs754452460, COSV56703351; called by muse, varscan2
- LRGUK | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV53637956; called by muse, mutect2, varscan2
- LRP1 | c.5922G>A p.W1974* | Nonsense Mutation (SNP) | VAF 32/386 reads (8%) | catalogued as rs1555185387; called by muse, mutect2
- LRP10 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 46/623 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs752169696; called by muse, mutect2
- LRP1B | c.6652C>T p.P2218S | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1202920373, COSV101250806; called by muse, mutect2
- LRP1B | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67184445, COSV67241706; called by muse, mutect2, varscan2
- LRP2 | c.5689C>T p.P1897S | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775502143; called by muse, mutect2, varscan2
5,845 further variants in this file (3,429 protein-altering or splice-affecting, 2,133 silent, 283 other) are not listed here.
